Gene-level copy-number profile of tumor specimen TCGA-13-1507-01A from TCGA case TCGA-13-1507, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.9 years (28,445 days).
Specimen TCGA-13-1507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bfed3408-33c3-40cd-9382-0bcf1b91af89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1507-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74b2d163-bd07-423f-a385-6418b65f5b91

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 1,866; copy number 2: 21,133; copy number 3: 28,342; copy number 4: 6,088; copy number 5: 764; copy number 6: 1,088; copy number 7: 233; copy number 8: 132; copy number 9: 10; copy number 10: 17; copy number 11: 95; copy number 13: 2; copy number 17: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1507-01A-01D-0472-01): tumor purity 0.73, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:26,291,508–26,382,953, 2 genes (within-gene range 0–2): PPP2R2A, SDAD1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 500 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:68,040,290–68,093,001, 1 gene, copy number 9 (within-gene range 6–9): AL646090.2.
- chr6:68,223,667–69,867,236, 9 genes, copy number 9 (within-gene range 3–9): AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42.
- chr8:46,028,804–49,229,174, 64 genes, copy number 8 (broad region; genes not listed).
- chr8:60,629,662–61,501,645, 13 genes, copy number 10 (within-gene range 4–10): AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1.
- chr8:65,526,738–65,634,217, 4 genes, copy number 10: LINC01299, AC100814.1, Y_RNA, ARMC1.
- chr8:68,293,446–68,331,689, 2 genes, copy number 13: RPL31P40, C8orf34-AS1.
- chr10:54,864,674–54,869,122, 1 gene, copy number 7: AC051618.1.
- chr10:73,497,538–73,625,953, 1 gene, copy number 7 (within-gene range 2–7): USP54.
- chr10:73,625,996–81,137,335, 175 genes, copy number 7–11 (broad region; genes not listed).
- chr18:21,242,242–21,525,417, 1 gene, copy number 11 (within-gene range 5–11): GREB1L.
- chr18:21,380,286–24,708,542, 83 genes, copy number 11–17 (broad region; genes not listed).
- chr18:44,280,768–44,579,953, 1 gene, copy number 7 (within-gene range 6–7): LINC01478.
- chr18:44,522,366–51,643,939, 145 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
